TCGA case TCGA-06-0167 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/afd3a4dc-a2e5-4545-92b8-a18e72fc9e94

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 44 years; Vital status: Dead; Days to death: 347 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 44.3 years (16,170 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 24 days; Days to treatment end: 68 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 24 days; Days to treatment end: 68 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 77 days; Days to treatment end: 197 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bortezomib; Days to treatment start: 258 days; Days to treatment end: 289 days.

Follow-up (2 entries)
- Days to follow up: 347 days; Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0167-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.7. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide TCGA-06-0167-01A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-06-0167-01A-01-BS1: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-06-0167-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 3: Pharmaceutical therapy drug name: PS341.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 347 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 347 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 347 days.
